Somatic mutation profile of tumor specimen MP2PRT-PAUXJG-TBP1-A (aliquot MP2PRT-PAUXJG-TBP1-A-1-0-D-A820-36) from MP2PRT case MP2PRT-PAUXJG, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.3 years (831 days).
Specimen MP2PRT-PAUXJG-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e6651cd1-3d3c-4f28-913d-57193c4c6e5b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUXJG-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUXJG-NB1-A-1-0-D-A820-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/01aee1b8-aefb-4a1f-b453-48edac4b05b7

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Silent 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EEF2 | c.2134G>A p.D712N | Missense Mutation (SNP) | VAF 74/751 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV58579201; called by muse, mutect2
- POSTN | c.61G>A p.A21T | Missense Mutation (SNP) | VAF 32/327 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs771038377, COSV65712186; called by muse, mutect2
- SF1 | c.1713dup p.G572Rfs*40 | Frame Shift Ins (INS) | VAF 60/612 reads (10%) | catalogued as rs1339885388; called by mutect2, pindel
- CYS1 | c.384C>T p.S128= | Silent (SNP) | VAF 21/440 reads (5%) | called by muse, mutect2
